Somatic mutation profile of tumor specimen BA2918D (aliquot aq-BA2918D) from BEATAML1.0 case 2007, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,670 days).
Specimen BA2918D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a3ed271-bded-4e87-85e1-dc8b09a3c60a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2014D (Solid Tissue Normal), aliquot aq-BA2014D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f86fa2ac-6883-471a-8768-0e05c247234d

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1, In Frame Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 45/91 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 30/141 reads (21%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 78/164 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 30/86 reads (35%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 60/466 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.7561C>T p.R2521C (on ENST00000560601 / NM_001369268.1; = p.R2483C on NM_013227.3) | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781181702, COSV61359578; called by muse, mutect2, varscan2
- AMHR2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs371910684; ClinVar: likely benign; called by muse, mutect2
- DACT1 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60021398; called by muse, mutect2, varscan2
- FAM153B | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs1184696449; called by mutect2, varscan2
- FREM2 | c.7663G>A p.V2555M | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs200997496, COSV54842960; called by muse, mutect2, varscan2
- MCF2L | c.731C>T p.T244M (on ENST00000375608; = p.T212M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); catalogued as rs376518005; called by muse, mutect2, varscan2
- NEK1 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs765158830; called by muse, mutect2, varscan2
- TGM1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs757697165; called by muse, mutect2, varscan2
- TMEM175 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs945983236; called by muse, mutect2, varscan2
- USP5 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV57536561; called by muse, mutect2, varscan2
- FRMD3 | c.1156T>C p.S386P | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- GPR156 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- INPP5J | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- KCNT2 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LMO7 | c.2748C>A p.Y916* (on ENST00000357063; = p.Y597* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- NUP205 | c.3286C>A p.Q1096K | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- C1orf43 | c.630G>A p.Q210= (on ENST00000368521 / NM_001297718.2; = p.Q176= on NM_015449.4) | Silent (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- DEDD | c.792C>A p.I264= | Silent (SNP) | VAF 119/255 reads (47%) | called by muse, mutect2, varscan2
- KCNK9 | c.660C>T p.Y220= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as rs111826894, COSV57280572; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAV3 | c.2445C>T p.V815= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs372264864; called by muse, mutect2, varscan2
- PDZRN3 | c.2019C>T p.A673= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as rs377349000; called by muse, mutect2, varscan2
- WSCD1 | c.147C>T p.P49= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as rs765749146; called by muse, varscan2
- AP000769.5 | chr11:65500909 ins A | 5'Flank (INS) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- EFHC1 | c.*1045T>A | 3'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as rs112794529; called by muse, mutect2, varscan2
- SNORD115-39 | n.58G>A | RNA (SNP) | VAF 114/297 reads (38%) | called by muse, mutect2, varscan2
